Somatic mutation profile of tumor specimen TCGA-IC-A6RF-01A (aliquot TCGA-IC-A6RF-01A-13D-A33E-09) from TCGA case TCGA-IC-A6RF, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 69.6 years (25,417 days).
Specimen TCGA-IC-A6RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fade1e37-cc29-41b5-95b5-df52e1be48ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IC-A6RF-10A (Blood Derived Normal), aliquot TCGA-IC-A6RF-10A-21D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5597bb9d-c8ca-4426-b0b1-bb57a59fdf75

The open-access MAF lists 121 somatic variants for this specimen: 84 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 36, Frame Shift Del 6, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs797045057, CM043040, CM051589, COSV61774888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4715+1G>C p.X1572_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); catalogued as rs1485723437, COSV57431126, COSV57439397; called by muse, mutect2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- SOX9 | c.454_501del p.R152_K167del | In Frame Del (DEL) | VAF 49/236 reads (21%) | hotspot (GDC flag); called by mutect2, pindel
- ADAMTSL1 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs779193184; called by muse, mutect2, varscan2
- CDH23 | c.6403G>A p.E2135K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56490507; called by muse, mutect2, varscan2
- COLGALT2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775167400, COSV62298785; called by muse, mutect2, varscan2
- CYB5R1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777291289, COSV65916873; called by muse, mutect2, varscan2
- HDLBP | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV60502048; called by muse, mutect2
- HNRNPL | c.1010dup p.P338Tfs*56 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs767148651; called by mutect2, varscan2
- KIF2B | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52130550; called by muse, mutect2, varscan2
- KREMEN1 | c.1073A>G p.Y358C (on ENST00000407188; = p.Y360C on NM_032045.5) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs766331382; called by muse, mutect2, varscan2
- LTBP1 | c.1171G>A p.D391N (on ENST00000404816 / NM_206943.4; = p.D65N on NM_000627.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375749254, COSV63182846; called by muse, mutect2, varscan2
- MARK1 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs761658090, COSV65065989; called by muse, mutect2, varscan2
- MUC5B | c.7852G>T p.A2618S | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV71592083; called by muse, mutect2, varscan2
- NES | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs747226593; called by muse, mutect2, varscan2
- NLRP11 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.189); catalogued as rs756060414; called by muse, mutect2, varscan2
- NSD1 | c.4705G>T p.E1569* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV61787431; called by muse, mutect2, varscan2
- OR10G2 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs372221393; called by muse, mutect2, varscan2
- RALGAPB | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs151316950; called by muse, mutect2, varscan2
- RNASE4 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs760452697, COSV104395170; called by muse, mutect2, varscan2
- SAMD14 | c.1085G>A p.G362E (on ENST00000330175 / NM_001257359.2; = p.G390E on NM_174920.4) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50303603; called by muse, mutect2, varscan2
- SLC4A10 | c.1229G>A p.R410H (on ENST00000446997 / NM_001354461.2; = p.R380H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs911712300; called by muse, mutect2, varscan2
- SPANXB1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 60/406 reads (15%) | catalogued as rs1218668228; called by muse, varscan2
- TAF1 | c.3481C>T p.R1161C (on ENST00000373790 / NM_138923.4; = p.R1182C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52125636; called by muse, mutect2, varscan2
- ZC3H14 | c.1130A>C p.Q377P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV51773669; called by muse, mutect2, varscan2
- ZNF496 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs770054959, COSV54177676; called by muse, mutect2, varscan2
- ZNF784 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100323274; called by muse, mutect2, varscan2
- ABCF3 | c.1113+1G>A p.X371_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- ADGRV1 | c.15481C>A p.L5161I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AMBRA1 | c.2375G>A p.R792H (on ENST00000458649 / NM_001367468.1; = p.R702H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD23 | c.264_265del p.H88Qfs*8 | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | called by pindel, varscan2
- ANO7 | c.1582G>T p.V528L (on ENST00000274979; = p.V474L on NM_001370694.2) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGEF2 | c.251C>T p.A84V (on ENST00000361247 / NM_001162383.2; = p.A57V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); called by muse, mutect2
- BMPER | c.494-1G>T p.X165_splice | Splice Site (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- CASP8 | c.483_484del p.R162Sfs*17 (on ENST00000432109 / NM_033355.3; = p.R194Sfs*17 on NM_001228.4) | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- CCDC85A | c.1088A>T p.K363I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CDH18 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CDH7 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CDKL2 | c.126_145del p.K42Nfs*11 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- COL12A1 | c.4127G>C p.C1376S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD2 | c.4230G>C p.Q1410H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- EDEM1 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EVL | c.965G>T p.G322V (on ENST00000402714 / NM_001330221.2; = p.G324V on NM_016337.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- GLIPR2 | c.21A>T p.K7N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLPH3L | c.547T>A p.F183I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- H2AC4 | c.365dup p.S123Efs*4 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- H2AC6 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- HARBI1 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- HOXD8 | c.533_542del p.Q178Lfs*9 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- IFI16 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IL1RAPL1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KCNA5 | c.734G>C p.S245T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KCNQ4 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- KLHL1 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- LAIR2 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMC1 | c.2674A>T p.M892L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAS1L | c.1574T>C p.I525T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LCP2 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2
- MYH8 | c.4041_4057del p.E1348Afs*6 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- NBPF3 | c.1033T>C p.S345P | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NDUFS1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUTM1 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PIAS4 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR1B | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEF | c.2814G>T p.K938N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PRPF40B | c.1908G>T p.M636I (on ENST00000380281; = p.M623I on NM_012272.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- PRSS35 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN21 | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PTPN23 | c.4810A>C p.N1604H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- RNF213 | c.13438C>A p.L4480I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ROR2 | c.1184-1G>A p.X395_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SAMD9L | c.2582T>C p.L861P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SELP | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFRP4 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC4A2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.685); called by muse, mutect2
- SPANXN1 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TAFA2 | c.302_305del p.C101* | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.89290C>G p.P29764A (on ENST00000591111; = p.P22340A on NM_003319.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- TTN | c.3232G>A p.E1078K (on ENST00000591111; = p.E1032K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- USP51 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- VPS13A | c.7895T>G p.V2632G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZMYM1 | c.2204A>G p.K735R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ZNF423 | c.2435G>A p.S812N (on ENST00000563137 / NM_001379286.1; = p.S804N on NM_015069.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ACOXL | c.138G>A p.A46= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs375666693; called by muse, varscan2
- ADAD1 | c.1185T>C p.L395= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.477C>T p.N159= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs975001115, COSV67131922; called by muse, mutect2, varscan2
- AMOT | c.1716C>A p.I572= (on ENST00000371959 / NM_001113490.1; = p.I163= on NM_133265.3) | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100495084; called by muse, mutect2, varscan2
- CASP5 | c.696C>T p.D232= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs754974875, COSV52827489; called by muse, mutect2, varscan2
- CD109 | c.2502C>T p.V834= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs143756315, COSV54645037; called by muse, mutect2, varscan2
- CPA5 | c.27G>A p.T9= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs782186925, COSV62569692; called by muse, mutect2, varscan2
- EVX1 | c.534C>T p.S178= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV56085617; called by muse, mutect2, varscan2
- FGF12 | c.138C>T p.L46= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs1304126779, COSV53175435; called by muse, mutect2, varscan2
- GNL3L | c.972C>T p.H324= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs745791161; called by muse, mutect2, varscan2
- GRAMD4 | c.876C>T p.D292= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.2139G>A p.S713= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs373644440; called by muse, mutect2, varscan2
- HSPA9 | c.1329G>A p.L443= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- JSRP1 | c.735G>A p.P245= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- KRT85 | c.900C>T p.D300= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs372918365; called by muse, mutect2, varscan2
- MAP3K6 | c.1698C>T p.S566= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1176050888; called by muse, mutect2, varscan2
- MEF2C | c.354G>A p.R118= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV60930798; called by muse, mutect2, varscan2
- PAPPA2 | c.2217G>T p.L739= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- PCSK5 | c.3699G>A p.E1233= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- PMEL | c.858C>G p.V286= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59386034; called by muse, mutect2, varscan2
- PRPF40B | c.1909C>T p.L637= (on ENST00000380281; = p.L624= on NM_012272.3) | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- PRRT1 | c.615G>A p.P205= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- RICTOR | c.4783T>C p.L1595= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- SEMA5A | c.546T>C p.A182= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- SINHCAF | c.79C>A p.R27= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- SLC18A3 | c.201C>T p.G67= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- SLC9A3 | c.642C>T p.F214= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs765455835, COSV53799561; called by muse, mutect2, varscan2
- TBC1D21 | c.996G>A p.K332= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- TNIP1 | c.1854C>T p.P618= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100161300; called by muse, mutect2, varscan2
- TPSAB1 | c.114C>G p.P38= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs772401742; called by muse, mutect2, varscan2
- TRIM58 | c.921C>T p.T307= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs201527424, COSV100824885; called by muse, mutect2, varscan2
- UNC5D | c.2400C>A p.T800= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV54826575; called by muse, mutect2, varscan2
- WASF3 | c.33G>A p.R11= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs1376534224; called by muse, mutect2, varscan2
- ZIC1 | c.1200C>T p.G400= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- ZMYM3 | c.3732C>A p.T1244= | Silent (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- ZNF664 | c.510C>A p.P170= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-23844G>A | Intron (SNP) | VAF 26/88 reads (30%) | catalogued as rs755419242; called by muse, mutect2, varscan2
